Gene-level copy-number profile of tumor specimen TCGA-DX-A1KZ-01A from TCGA case TCGA-DX-A1KZ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.7 years (24,362 days).
Specimen TCGA-DX-A1KZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.362bf99a-94f3-4f60-9778-41ea7a0ca550.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1KZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bd132f15-dc32-4858-8c68-dc52b49a76b6

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,053; copy number 2: 5,646; copy number 3: 8,503; copy number 4: 31,577; copy number 5: 7,967; copy number 6: 1,151; copy number 7: 231; copy number 8: 368; copy number 9: 615; copy number 10: 374; copy number 11: 276; copy number 12: 303; copy number 13: 194; copy number 14: 237; copy number 15: 232; copy number 16: 43; copy number 17: 267; copy number 18: 114; copy number 19: 75; copy number 20: 157; copy number 21: 52; copy number 22: 16; copy number 23: 30; copy number 25: 50; copy number 26: 53; copy number 28: 24; copy number 29: 6; copy number 30: 6; copy number 31: 1; copy number 32: 66; copy number 33: 2; copy number 35: 10; copy number 36: 9; copy number 37: 1; copy number 38: 40; copy number 42: 14; copy number 44: 1; copy number 47: 5; copy number 48: 14; copy number 49: 23; copy number 55: 3; copy number 67: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1KZ-01A-11D-A24M-01): tumor purity 0.49, ploidy 4.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,314 genes in 105 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:121,178,327–121,809,962, 15 genes, copy number 12–23: AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823.
- chr2:129,825,126–131,047,263, 76 genes, copy number 20 (within-gene range 5–20) (broad region; genes not listed).
- chr2:135,531,455–136,545,542, 18 genes, copy number 18 (within-gene range 5–18): R3HDM1, RNU6-512P, MIR128-1, UBXN4, LCT, Y_RNA, LCT-AS1, MCM6, MANEALP1, DARS1, DARS-AS1, AC068492.1, CXCR4, HNRNPKP2, AC112255.1, UBBP1, RN7SKP141, SMC4P1.
- chr3:141,487,027–142,578,733, 25 genes, copy number 9–17 (within-gene range 4–17): RASA2, RASA2-IT1, YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2.
- chr5:4,012,708–5,320,304, 19 genes, copy number 9–13 (within-gene range 5–13): AC025773.1, AC025187.1, LINC02063, AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1.
- chr5:8,157,541–9,712,378, 35 genes, copy number 13–19 (within-gene range 8–19): AC091912.1, AC091912.3, LINC02226, AC091965.1, AC091965.3, AC091965.4, MIR4458HG, AC091965.2, AC091965.5, MIR4458, AC091953.1, AC091953.3, AC091953.5, MTND6P2, MTCYBP37, AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1.
- chr5:10,057,502–16,033,356, 80 genes, copy number 15–20 (broad region; genes not listed).
- chr5:16,661,907–17,670,571, 49 genes, copy number 13: MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2, RNU6-1003P, AC026785.1, RN7SKP133, FTH1P10, AC026785.2, AC026785.3, LINC02111, LINC02217, LINC02218, H3Y2, AC106774.1, TAF11L2, H3P17, H3P18, TAF11L3, TAF11L4, TAF11L5, TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21, TAF11L13, TAF11L14, AC233724.4, AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22.
- chr5:25,087,450–40,984,643, 232 genes, copy number 16–22 (broad region; genes not listed).
- chr5:115,031,273–115,626,161, 19 genes, copy number 32 (within-gene range 4–32): AC094104.2, AC094104.1, TRIM36, TRIM36-IT1, AC008494.2, PGGT1B, AC008494.3, AC008494.1, CCDC112, HMGN1P15, CTNNA1P1, AK3P4, AC008628.2, AC008628.1, CCT5P1, FEM1C, TICAM2, TMED7-TICAM2, AC010226.1.
- chr5:159,698,586–160,852,214, 23 genes, copy number 28: LINC01847, ADRA1B, GAPDHP40, Y_RNA, TTC1, AC068657.1, PWWP2A, FABP6, FABP6-AS1, AC112191.1, CCNJL, AC112191.2, AC112191.3, C1QTNF2, ZBED8, SLU7, PTTG1, MIR3142HG, MIR3142, MIR146A, ATP10B, AC008456.1, AC011363.1.
- chr5:172,690,454–174,330,503, 47 genes, copy number 12–20 (within-gene range 7–20): AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1, AC008632.1, AC008663.1, AC008663.3, AC008663.2, BOD1, LINC01863, LINC01942, LINC01484, AC008674.1, LINC01485, CPEB4, C5orf47, RPL12P22, NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1.
- chr6:115,358,498–153,938,992, 578 genes, copy number 9–26 (broad region; genes not listed).
- chr8:15,806,149–17,413,528, 18 genes, copy number 9: PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7.
- chr8:73,215,929–75,566,834, 52 genes, copy number 11: AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1, STAU2, AC018620.1, AC100784.1, VENTXP6, AC027018.1, AC022826.2, UBE2W, AC022826.1, RN7SL760P, AC022868.1, GYG1P1, ELOC, TMEM70, RPS20P21, DSTNP3, LY96, RNU6-1300P, AC087672.2, RPS3AP32, RNU6-1197P, AC087627.1, AC087672.1, JPH1, GDAP1, AC103952.1, Y_RNA, MIR5681A, MIR5681B, MIR2052HG, PCBP2P2, AC115837.1, MIR2052, AC011632.1, AC026616.1, PI15, AC011632.2, CRISPLD1, AC100782.1, CASC9, LINC02886, HIGD1AP6, PKMP4, HNF4G.
- chr8:83,099,976–104,589,024, 382 genes, copy number 10–13 (broad region; genes not listed).
- chr8:116,938,207–124,580,648, 117 genes, copy number 9 (broad region; genes not listed).
- chr8:132,024,216–134,390,487, 37 genes, copy number 9 (within-gene range 8–9): OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1.
- chr8:139,460,062–145,066,685, 210 genes, copy number 9–12 (broad region; genes not listed).
- chr9:72,445,754–76,399,586, 40 genes, copy number 9: AL445646.1, AL596448.1, TMC1, RPS20P24, RPS27AP15, LINC01474, ALDH1A1, CYP1D1P, ANXA1, DPP3P2, AL451127.2, AL451127.1, AL512594.1, RNA5SP286, AL513124.1, AL355674.1, RORB-AS1, RORB, AL137018.1, TRPM6, RN7SKP47, RPSAP75, RNU6-445P, AL158825.1, C9orf40, CARNMT1-AS1, CARNMT1, AL158825.2, AL158825.3, NMRK1, OSTF1, Y_RNA, RNU6-1228P, AL158073.1, AL353780.1, OTX2P1, PCSK5, RBM22P5, RFK, RPSAP9.
- chr9:83,200,940–84,340,758, 24 genes, copy number 12: RN7SKP242, AL137847.3, AL137847.1, FRMD3, AL137847.2, RNU4-29P, RNU4-15P, IDNK, UBQLN1, AL354920.1, GKAP1, AL354733.1, AL354733.2, KIF27, C9orf64, HNRNPK, MIR7-1, AL354733.3, RMI1, Y_RNA, AL390838.1, AL390838.2, SLC28A3, AL356134.1.
- chr9:96,235,306–99,377,240, 87 genes, copy number 12 (within-gene range 8–12) (broad region; genes not listed).
- chr9:107,283,137–108,703,092, 20 genes, copy number 12 (within-gene range 6–12): RAD23B, LINC01509, AL359552.1, HMGN2P32, RNU6-492P, KLF4, AL389915.1, PPIAP88, RNU6-996P, RNU6-1064P, RN7SL659P, RPL36AP6, AL162389.1, RNA5SP293, RPS15AP27, AC068050.1, CHCHD4P2, AL353742.1, AL669983.1, AL358779.1.
- chr9:111,686,173–112,472,405, 18 genes, copy number 13 (within-gene range 5–13): SHOC1, AL354877.1, RNU6-1013P, UGCG, MIR4668, RNU6-710P, AL138756.1, SUSD1, RNU6-855P, Y_RNA, AL158824.1, PTBP3, RN7SL57P, RNA5SP295, RN7SL430P, HSPE1P28, AL359073.1, HSDL2.
- chr10:1,290,018–5,666,595, 83 genes, copy number 9 (broad region; genes not listed).
- chr10:12,877,459–16,817,463, 75 genes, copy number 15 (within-gene range 4–15) (broad region; genes not listed).
- chr10:122,697,709–126,421,879, 75 genes, copy number 9 (broad region; genes not listed).
- chr12:2,332,861–2,954,338, 24 genes, copy number 19: AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P.
- chr12:6,310,436–6,538,374, 20 genes, copy number 11–21: PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH.
- chr12:7,566,369–8,188,537, 40 genes, copy number 38: GAPDHP31, NIFKP3, AC006927.1, AC006927.2, AC006927.4, AC006927.3, AC006927.5, APOBEC1, GDF3, DPPA3, CLEC4C, NANOGNB, Y_RNA, NANOG, Y_RNA, SLC2A14, AC006517.2, Y_RNA, Metazoa_SRP, AC006517.1, AC124891.1, NANOGP1, AC007536.1, SLC2A3, AC006511.6, Y_RNA, AC006511.1, AC006511.4, HSPD1P12, AC006511.2, FOXJ2, C3AR1, NECAP1, AC006511.3, AC006511.5, CLEC4A, POU5F1P3, AC092111.3, GCSHP4, ZNF705A.
- chr12:10,750,188–11,251,389, 31 genes, copy number 25 (within-gene range 4–25): LINC02366, HSPE1P12, TAS2R7, TAS2R8, TAS2R9, PRH1, TAS2R10, AC006518.1, PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2.
- chr12:25,936,683–27,014,434, 21 genes, copy number 16–47: RASSF8-AS1, RASSF8, BHLHE41, SSPN, AC022509.3, AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1.
- chr12:57,520,710–58,244,865, 42 genes, copy number 32: MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:59,322,765–61,232,937, 16 genes, copy number 18–25: AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1.
- chr12:67,440,998–68,971,570, 42 genes, copy number 15–49 (within-gene range 5–49): LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,713,633–75,209,839, 65 genes, copy number 9–55 (broad region; genes not listed).
- chr19:94,062–617,159, 33 genes, copy number 13: OR4G3P, OR4G1P, OR4F17, WBP1LP11, OR4F8P, AC092192.1, SEPTIN14P19, CICP19, AC092299.1, AC010507.1, LINC01002, AC010507.2, RNU6-1076P, AC016588.2, PLPP2, MIER2, AC016588.1, THEG, AC010641.2, AC010641.1, C2CD4C, SHC2, RNA5SP462, ODF3L2, MADCAM1, AC005775.1, TPGS1, CDC34, GZMM, AC009005.1, BSG, HCN2, AC005559.1.
- chr19:3,538,261–3,942,416, 26 genes, copy number 14: MFSD12, C19orf71, AC005786.3, AC005786.2, AC005786.4, AC005786.1, HMG20B, GIPC3, TBXA2R, CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1, TJP3, APBA3, AC005954.2, AC005954.1, MRPL54, RAX2, AC005777.1, MATK, ZFR2, FTLP5, ATCAY, RN7SL202P, NMRK2.
- chr20:5,890,055–7,633,851, 29 genes, copy number 14: RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1, LINC01428, AL080248.1, LINC01751, LINC01706, MIR8062, RN7SL547P.
- chr20:58,218,495–64,313,132, 204 genes, copy number 10–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 588. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
